Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6988, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6988-01A (Primary Tumor).

[page 1 of 7]
Pathology Report [REDACTED] **CORRECTED**

Report Type Pathology Report

Date of Event [REDACTED]

Sex M

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status CORRECTED

ADDENDA:

Addendum

PROBE: LSI EGFR/CEP7 Dual-Color Probe ([REDACTED])

Cytogenetic Location: 7p12 / 7p11.1-q11.1

EGFR FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.

Number of cells analyzed: 63

Ratio EGFR/CEP7: 1.08

High Polysomy: 0%

SNR (signal to nucleus ratio): 2.7

Low Polysomy: 10(15.9%)

Trisomy: 13(20.6%)

Disomy: 40(63.5%)

EGFR FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the EGFR SpectrumOrange and the CEP7 SpectrumGreen probes.

EGFR FISH positive:

High Polysomy: > four gene copies in > 40% of cells

Gene Amplification: Ratio gene/chromosome more than two or > 15 gene copies in > 10% of cells

EGFR FISH negative:

Disomy: < two gene copies in more than 90% of the cells

Trisomy: three gene copies in more than 10% of cells

Low Polysomy: > four gene copies in more than 10% but less than 40% of cells

References:

[REDACTED]

Pathologist: [REDACTED]

**** Report Electronically Signed Out ****

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

Addendum

Ancillary studies were performed and the results are as follows:

Stain	Result
P16	Negative
EGFR	Positive, membranous, 2+
HPV	Negative

[page 2 of 7]
[REDACTED]

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT, LEVELS 2, 3 AND 4, SELECTIVE DISSECTION

A. METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF THE THIRTY-SIX LYMPH NODES (2/36).

B. METASTATIC LYMPH NODES ARE IN LEVEL 2, 1.0 AND 2.0 CM.

C. NO EXTRACAPSULAR SPREAD.

PART 2: LYMPH NODES, LEFT, LEVELS 2, 3 AND 4, SELECTIVE DISSECTION

FORTY-FIVE LYMPH NODES, NO TUMOR PRESENT (0/45).

PART 3: LARYNX, RIGHT THYROID LOBE, TRACHEOSTOMY, TOTAL LARYNGECTOMY

A. INVASIVE SQUAMOUS CELL CARCINOMA, KERATINIZING, POORLY DIFFERENTIATED (4.0 cm), RIGHT GLOTTIC WITH SUPRAGLOTTIC (TRANSGLOTTIC) AND SUBGLOTTIC EXTENSION WITH INVOLVEMENT OF THYROID CARTILAGE.

B. NO PERINEURAL INVASION.

C. MARGINS FREE (see also 4, 5, 6 and 7).

D. PATHOLOGIC STAGE: pT4 N2B.

E. UNREMARKABLE THYROID PARENCHYMA.

F. STATUS POST TRACHEOSTOMY WITH OSTOMY RELATED REACTIVE CHANGES.

PART 4: PHARYNX, INFERIOR RIGHT PHARYNGEAL MUCOSAL MARGIN, EXCISION

NO TUMOR PRESENT.

PART 5: PHARYNX, RIGHT SUPERIOR PHARYNGEAL MARGIN, EXCISION

FOCAL MILD DYSPLASIA (ONLY PRESENT ON THE ORIGINAL FROZEN SECTION SLIDE), NO TUMOR PRESENT.

PART 6: CONSTRUCTOR MUSCLE, RIGHT INFERIOR, EXCISION

NO TUMOR PRESENT.

PART 7: CONSTRUCTOR MUSCLE, RIGHT PHARYNGEAL, EXCISION

NO TUMOR PRESENT.

[REDACTED]

Pathologist: [REDACTED]

** Report Electronically Signed Out **

By Pathologist: [REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in seven parts.

Part 1 is received unfixed with the patient's name, initials XXX, and "right neck dissection levels 2, 3, and 4". It consists of an 11.5 x 5.0 x 1.0 cm tan-yellow lobulated fibrofatty soft tissue fragment with a suture identifying level IIB. The specimen is divided into levels II, III, and IV based on this suture site. Level II is sectioned to reveal multiple possible tan brown lymph nodes, 0.2 x 0.2 x 0.1 cm to 2.5 x 1.4 x 1.0 cm. The largest lymph nodes are bisected to reveal a white firm cut surface. Level III is sectioned to reveal multiple possible tan-brown lymph nodes, 0.3 x 0.2 x 0.2 cm to 1.3 x 1.0 x 0.6 cm. The largest lymph node is bisected to reveal a tan cut surface. Level IV

[page 3 of 7]
is sectioned to reveal multiple possible tan-brown lymph nodes, 0.3 x 0.2 x 0.2 cm to 0.8 x 0.6 x 0.4 cm.

Representative sections are submitted as follows:

1A-B- level II possible lymph nodes

1C- level II, two possible lymph nodes, bisected

1D- level II, single possible lymph node, bisected

1E-F- level III, possible lymph nodes

1G- level III, single possible lymph node, bisected

1H-I- level IV possible lymph nodes

Part 2 is received unfixed with the patient's name, initials XXX, and "left neck dissection levels 2, 3, and 4". It consists of an 11.2 x 4.0 x 1.2 cm tan-yellow lobulated fibrofatty soft tissue fragment with a suture identifying level IIB. The specimen is divided into levels II, III, and IV based on this suture site. Level II is sectioned to reveal multiple possible tan-brown lymph nodes, 0.3 x 0.2 x 0.1 cm to 2.5 x 1.0 x 0.8 cm. The largest possible lymph node is bisected to reveal a tan-brown cut surface. Level III is sectioned to reveal multiple tan-brown possible lymph nodes, 0.3 x 0.1 x 0.1 cm to 1.6 x 0.7 x 0.4 cm. Level IV is sectioned to reveal multiple tan-brown possible lymph nodes, 0.2 x 0.1 x 0.1 cm to 2.0 x 0.9 x 0.6 cm. The largest possible lymph node is bisected to reveal a purple tan cut surface.

Representative sections are submitted as follows:

2A-B- level II possible lymph nodes

2C- level II single possible lymph node, bisected

2D-E- level III possible lymph nodes

2F- level III (two) possible lymph nodes

2G- level IV possible lymph nodes

2H- level IV (two) possible lymph nodes

2I- level IV possible lymph node, bisected

Part 3 is received fresh with the patient's name, initials XXX, and "total laryngectomy". It consists of a total laryngectomy (9.0 cm SI x 7.5 cm ML x 5.0 cm AP) with two attached tracheal rings, right lobe of thyroid (3.9 x 2.7 x 1.5 cm), associated soft tissue, and ring of tan-brown skin from tracheostomy site (2.0 x 2.0 cm with a 1.0 cm in diameter hole).

The mucosal surface is tan brown showing a 1.8 x 1.5 cm ulceration. Sectioning through this area reveals a 4.0 X 2.5 X 2.0 cm ill-defined white granular focally hemorrhagic transglottic tumor mass, involving the right true cord, ventricle, and false cord extending to the anterior commissure. It occupies the right pyriform recess involving the thyroid cartilage, abutting the posterior soft tissue resection margin, and extending 1.2 cm from the superior, 1.5 cm from the inferior, and 1.5 cm from the anterior resection margins. The posterior soft tissue margin was submitted for touch prep intraoperative consult.

The mucosal surface of the left true and false vocal cords is smooth and unremarkable. The right lobe of thyroid has an unremarkable mahogany red parenchyma and is 0.3 cm from the tumor mass. The attached soft tissue shows fibrofatty tissue and skeletal muscle which is abutted by the tumor mass.

Gross photographs are taken. Tumor and normal tissue are bulk frozen.

Ink code:

Black- anterior soft tissue margin

Blue- posterior soft tissue margin

Orange- anterior aspect after removal of the hyoid bone, not true margin

Green- base of tongue

Section code:

3A- tracheal resection margin, shave

3B-C- right posterior soft tissue resection margin, perpendicular

3D- left lateral mucosal resection margin, shave

[page 4 of 7]
3E- pre-epiglottic soft tissue margin, perpendicular
3F- superior mucosal margin, shave
3GDR- tumor and thyroid cartilage, following decalcification
3H- anterior soft tissue resection margin, perpendicular
3I- anterior commissure
3J- right false and true vocal cord and tumor
3K- left false and true vocal cord
3L- tumor and uninvolved mucosa
3MDR- right lobe of thyroid and tumor, following decalcification
3N- skin (tracheostomy site)

Part 4 is received fresh with the patient's name, initials XXX, and "inferior right mucosa, pharyngeal mucosal margin". It consists of a 2.0 x 0.8 x 0.2 cm tan-brown glistening mucosal soft tissue fragment. The specimen is submitted in toto for frozen intraoperative consult and permanent embedding in cassette 4AFS.

Part 5 is received fresh with the patient's name, initials XXX, and "right superior pharyngeal mucosal margin". It consists of two, 0.4 x 0.2 x 0.1 and 0.6 x 0.3 x 0.2 cm gray-white tan-brown glistening mucosal soft tissue fragments. The specimen is submitted in toto for frozen intraoperative consult and permanent embedding in cassette 5AFS.

Part 6 is received fresh with the patient's name, initials XXX, and "right inferior constrictor true paraglottic margin". It consists of a 4.5 x 1.6 x 0.8 cm tan-brown to yellow roughened soft tissue fragment with a suture identifying the superior true paraglottic margin (inked blue). The specimen is bisected to reveal a homogenous/slightly trabeculated cut surface and submitted in toto for frozen intraoperative consult and permanent embedding in cassettes 6AFS-BFS.

Part 7 is received unfixed with the patient's name, initials XXX, and "right pharyngeal constrictor". It consists of a 4.0 x 1.5 x 1.2 cm tan-brown yellow fibrofatty soft tissue fragment with a suture identifying the superior margin. The specimen is inked black and serially sectioned from superior to inferior revealing a tan-yellow homogeneous cut surface.

The specimen is submitted in toto as follows:

7A- superior margin, shave

7B-C- remainder of soft tissue, superior to inferior

Dictated by: [REDACTED]

INTRAOPERATIVE CONSULTATION:

3ATP: TOTAL LARYNGECTOMY, RIGHT POSTERIOR SOFT TISSUE MARGIN (touch prep)

A. MALIGNANT

B. GROSSLY, SQUAMOUS CELL CARCINOMA EXTENDS TO MARGIN [REDACTED]

4AFS: INFERIOR RIGHT MUCOSA, PHARYNGEAL MUCOSA MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. NO TUMOR [REDACTED]

5AFS: RIGHT SUPERIOR, PHARYNGEAL MUCOSA MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. DEFER

C. MINUTE FOCUS OF MILD TO MODERATE ATYPIA [REDACTED]

6AFS: RIGHT INFERIOR CONSTRUCTOR, TRUE PARAGLOTTIC MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. NO TUMOR [REDACTED]

6BFS: RIGHT INFERIOR CONSTRUCTOR, TRUE PARAGLOTTIC MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

[page 5 of 7]
C. NO TUMOR

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the Department of Pathology, as required by the CLIA regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - LARYNX RESECTIONS

TYPE OF LARYNGECTOMY: Total

TUMOR LATERALITY: Right, Bilateral

ATTACHED STRUCTURES: Tracheotomy, Other: right thyroid lobe

TUMOR LOCATION/SEGMENT: Transglottic

TUMOR SIZE: Maximum dimension: 4.0 cm

HISTOLOGIC TYPE OF TUMOR: Squamous cell carcinoma

HISTOLOGIC GRADE: Poorly differentiated/Undifferentiated

STRUCTURES INVOLVED BY TUMOR: True cord, Anterior commissure, False cord, Ventricle, Subglottis (greater than 1 cm subglottic extension), Thyroid cartilage, Paraglottic space, Other: right posterior soft tissues

LYMPH NODES: Lymph nodes positive, Right: 2

Total number of right sided lymph nodes examined: 36

Lymph nodes positive, Left: 0

Total number of left sided lymph nodes examined: 45

EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES

No

INTRA-PERINEURAL INVASION: Absent

VASCULAR INVASION: Yes

SURGICAL MARGIN INVOLVEMENT: Free (2 mm or more)

T STAGE, PATHOLOGIC: Glottis, pT4a

N STAGE, PATHOLOGIC: pN2b

M STAGE, PATHOLOGIC: pMX

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Laryngeal cancer.

PROCEDURE: Total laryngectomy, bilateral neck.

SPECIFIC CLINICAL QUESTION: Dissection, TE puncture

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMOTHERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

[page 6 of 7]
Part 1: Right Neck Dissection Level 2, 3,4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

DOG1 x 1 D

ANEG x 1 D

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

Part 2: Left Neck Dissection Level 2, 3,4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

Part 3: Total Laryngectomy

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 H

H&E x 1 I

H&E x 1 J

H&E x 1 K

DOG1 x 1 L

ANEG x 1 L

H&E Recut x 1 L

IEGFR x 1 L

IBNKNC x 1 L

IBNKNC x 1 L

IBNKNC x 1 L

IBNKNC x 1 L

IBNKNC x 1 L

IBNKNC x 1 L

H&E x 1 L

HPV x 1 L

IISH x 1 L

P16 x 1 L

V-EGFR x 1 L

H&E x 1 N

Decal x 1 GDR

[page 7 of 7]
H&E x 1 GDR

Decal x 1 MDR

H&E x 1 MDR

Part 4: Inferior Right Mucosa Pharyngeal Margin

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 5: Right Superior Pharyngeal Margin

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 6: Right Inferior Constrictor

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

H&E x 1 BFS

Part 7: Right Pharyngeal Constrictor

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

TC1

Source: NCI Genomic Data Commons file f0687563-f3ec-419c-9fc8-54ec241ff8d6 (TCGA-CN-6988.2CC61109-A96E-4221-B1BA-DE30FEABAE54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).